CCDI case PBBTXA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/4fa32e68-b7e2-4d9f-a275-4c9c27159af7

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Angiomyosarcoma: ICD-O-3 morphology code: 8894/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 14.8 years (5,407 days).

Biospecimens (3 samples)
- Sample 0DGYZ2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGZAE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGZFH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
